Gene-level copy-number profile of specimen HCM-BROD-0477-C16-85M from HCMI case HCM-BROD-0477-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: GX; Age at diagnosis: 68.6 years (25,046 days).
Specimen HCM-BROD-0477-C16-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 840184e2-aac9-452b-8e33-3fa112223301.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0477-C16-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/65c2756a-c978-4d7d-8399-9bbe3cd77c91

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 2,094; copy number 2: 11,193; copy number 3: 17,924; copy number 4: 21,945; copy number 5: 3,243; copy number 6: 2,128; copy number 7: 341; copy number 8: 12; copy number 10: 5; copy number 12: 25.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:75,588,058–75,626,849, 1 gene (within-gene range 0–2): MYO15B.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 30 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:38,699,274–38,853,028, 5 genes, copy number 10: AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2.
- chr21:24,840,550–25,772,460, 25 genes, copy number 12: LINC01692, AP000402.1, AP000146.1, AP001342.1, AP000235.1, AP000233.2, RN7SKP236, AP000233.1, AP001341.1, RNA5SP489, RPL13AP7, AP001340.1, LINC00158, AP000221.1, MIR155HG, MIR155, AP000223.1, MRPL39, JAM2, RNGTTP1, AP000224.1, FDX1P2, ATP5PF, GABPA, LLPHP2.

Autosomal genes at a single copy (total copy number 1): 1,770. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
